Gene-level copy-number profile of specimen HCM-STAN-0848-C20-85A from HCMI case HCM-STAN-0848-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen HCM-STAN-0848-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8bb62b0-348f-4649-823c-e9cd9a06fcf6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0848-C20-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,750 have no estimate.
https://portal.gdc.cancer.gov/files/39fdd44a-69d6-478d-b460-b2603caf5cec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 7,397; copy number 2: 42,780; copy number 3: 5,553; copy number 4: 1,828; copy number 5: 1,303; copy number 6: 1; copy number 8: 2; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–1): RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,307 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene, copy number 8: ADAM3A.
- chr13:18,609,132–46,161,379, 537 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:47,307,082–61,805,676, 196 genes, copy number 5 (broad region; genes not listed).
- chr13:61,997,136–63,097,797, 9 genes, copy number 5: LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, LINC00448, AL354810.1.
- chr13:63,667,681–114,337,626, 561 genes, copy number 5 (broad region; genes not listed).
- chr15:30,254,402–30,348,236, 3 genes, copy number 6–9: RNU6-17P, AC135731.2, AC019322.4.

Autosomal genes at a single copy (total copy number 1): 6,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
